Somatic mutation profile of tumor specimen TCGA-55-7994-01A (aliquot TCGA-55-7994-01A-11D-2184-08) from TCGA case TCGA-55-7994, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.7 years (29,858 days).
Specimen TCGA-55-7994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 778cde8c-6445-4b59-9185-3cc50f51836d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7994-10A (Blood Derived Normal), aliquot TCGA-55-7994-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03add666-b87c-414c-8695-5667f3b599c1

The open-access MAF lists 1,704 somatic variants for this specimen: 1,287 protein-altering or splice-affecting, 363 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,093, Silent 363, Nonsense Mutation 91, Frame Shift Del 49, Splice Site 27, Intron 23, RNA 20, Frame Shift Ins 13, Splice Region 8, 3'UTR 4, 3'Flank 3, Translation Start Site 2.

Variants (750 of 1,704; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1085308014, COSV100796784; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs187195559, COSV100229327; called by muse, mutect2, varscan2
- AARS1 | c.2671A>G p.T891A | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99933719; called by muse, mutect2, varscan2
- ABAT | c.991G>T p.G331* | Nonsense Mutation (SNP) | VAF 11/123 reads (9%) | catalogued as COSV99191016; called by muse, mutect2
- ABCA13 | c.5149G>C p.A1717P | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV101330157; called by muse, mutect2, varscan2
- ABCA9 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100383397; called by muse, mutect2, varscan2
- ABCB11 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55596141, COSV99792804; called by muse, mutect2, varscan2
- ABCB5 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as COSV99329314; called by muse, mutect2, varscan2
- ABCF3 | c.1750+1G>T p.X584_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99491627; called by muse, mutect2, varscan2
- ABCG5 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99575573; called by muse, mutect2, varscan2
- ABHD12B | c.532+1G>A p.X178_splice (on ENST00000337334 / NM_001206673.2; = p.X101_splice on NM_181533.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100485801; called by muse, mutect2, varscan2
- ABHD4 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99360601; called by muse, mutect2, varscan2
- ABI3BP | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99428259; called by muse, mutect2, varscan2
- ABR | c.2014G>A p.E672K (on ENST00000302538 / NM_021962.5; = p.E635K on NM_001092.5) | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV52146098, COSV99348456; called by muse, mutect2, varscan2
- ACACB | c.6676G>T p.G2226C | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100623230; called by muse, mutect2, varscan2
- ACADL | c.1230C>G p.I410M | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99285009; called by muse, mutect2
- ACE | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99327613; called by muse, mutect2, varscan2
- ACOT12 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs371159125; called by muse, mutect2, varscan2
- ACP7 | c.616C>G p.H206D | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100488590; called by muse, mutect2, varscan2
- ACSBG2 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.204); catalogued as COSV99397610; called by muse, mutect2, varscan2
- ACTN2 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100856945; called by muse, mutect2, varscan2
- ADAM12 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV100901250; called by muse, mutect2, varscan2
- ADAM33 | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as COSV62935940; called by muse, mutect2, varscan2
- ADAMTS3 | c.1035C>G p.N345K | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as COSV99711854; called by muse, mutect2, varscan2
- ADAMTS9 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99900048; called by muse, mutect2, varscan2
- ADAMTSL1 | c.853G>C p.A285P | Missense Mutation (SNP) | VAF 63/97 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as COSV99444412; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2251C>G p.R751G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101002029; called by muse, mutect2, varscan2
- ADGRG4 | c.1427C>A p.T476K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV99794205; called by muse, mutect2, varscan2
- ADGRG4 | c.2927C>A p.T976N | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV99796421; called by muse, mutect2, varscan2
- ADGRG4 | c.3457A>G p.I1153V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99796423; called by muse, mutect2
- ADGRL3 | c.920G>T p.S307I (on ENST00000506720 / NM_001322402.2; = p.S239I on NM_015236.6) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101547356; called by muse, mutect2
- ADGRL4 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100876468, COSV66061402; called by muse, mutect2, varscan2
- ADGRL4 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs745409718, COSV100876470; called by muse, mutect2, varscan2
- ADGRV1 | c.3955C>G p.R1319G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs372789540, COSV101316359, COSV67989114; called by muse, mutect2, varscan2
- ADNP | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100823840; called by muse, mutect2, varscan2
- ADORA2A | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418119; called by muse, mutect2, varscan2
- ADSS2 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV100836896; called by muse, mutect2, varscan2
- AFF1 | c.1717del p.A573Pfs*73 | Frame Shift Del (DEL) | VAF 17/29 reads (59%) | catalogued as COSV57120899; called by mutect2, varscan2
- AFG1L | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100933898; called by muse, mutect2, varscan2
- AGMO | c.127-1G>T p.X43_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100694621; called by muse, mutect2, varscan2
- AGO1 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs773266381, COSV100940909; called by muse, mutect2, varscan2
- AGPAT4 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100211896; called by muse, mutect2, varscan2
- AGPS | c.636A>T p.P212= | Splice Region (SNP) | VAF 29/99 reads (29%) | catalogued as COSV99931650; called by muse, mutect2, varscan2
- AHCTF1 | c.5045G>T p.S1682I (on ENST00000366508; = p.S1656I on NM_015446.5) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV100404289; called by muse, mutect2, varscan2
- AHCTF1 | c.5044A>T p.S1682C (on ENST00000366508; = p.S1656C on NM_015446.5) | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100404291; called by muse, mutect2, varscan2
- AHNAK | c.6865G>C p.E2289Q | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99945132, COSV99949132; called by muse, mutect2, varscan2
- AHNAK2 | c.12703C>A p.Q4235K | Missense Mutation (SNP) | VAF 79/236 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV100318672; called by muse, mutect2, varscan2
- AHNAK2 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.133); catalogued as COSV100318674; called by muse, mutect2, varscan2
- AJAP1 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs768152046, COSV65454601; called by muse, mutect2
- AKAP6 | c.3000+1G>T p.X1000_splice | Splice Site (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99803678; called by muse, mutect2, varscan2
- AL031777.2 | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100587258; called by muse, mutect2
- ALB | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99892055; called by muse, mutect2, varscan2
- ALDH16A1 | c.1306G>T p.G436W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99513168; called by muse, mutect2, varscan2
- ALDOA | c.1211G>T p.G404V (on ENST00000642816 / NM_001243177.4; = p.G350V on NM_184041.5) | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100582204; called by muse, mutect2, varscan2
- ALK | c.4307G>A p.R1436H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs544926207, COSV66588529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.2777G>A p.G926E | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490348940, COSV66589966; called by muse, mutect2, varscan2
- ALX4 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100241228; called by muse, mutect2, varscan2
- ANGPTL5 | c.995G>C p.G332A | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100527960; called by muse, mutect2, varscan2
- ANK2 | c.6667C>A p.P2223T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs762987114, COSV100003648; called by muse, mutect2, varscan2
- ANK3 | c.11562G>C p.K3854N | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV99781855; called by muse, mutect2, varscan2
- ANKEF1 | c.863G>T p.R288M | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV101001061; called by muse, mutect2, varscan2
- ANKRD11 | c.4577G>T p.G1526V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99970374; called by muse, mutect2, varscan2
- ANKRD17 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429831; called by muse, mutect2, varscan2
- ANKRD28 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV101080892; called by muse, mutect2, varscan2
- ANKRD30A | c.2819C>A p.P940H (on ENST00000611781; = p.P884H on NM_052997.2) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV100654271; called by muse, mutect2, varscan2
- ANKRD42 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV99474070; called by muse, mutect2, varscan2
- ANPEP | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 116/246 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs986360874, COSV100263442; called by muse, mutect2, varscan2
- AP1M1 | c.119A>T p.K40M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.152); catalogued as COSV99358608; called by muse, mutect2, varscan2
- AP5Z1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100804208; called by muse, mutect2, varscan2
- APC2 | c.1963C>A p.R655S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99279775; called by muse, mutect2, varscan2
- APLNR | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951618; called by muse, mutect2, varscan2
- APLP2 | c.1067G>C p.C356S | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99600008; called by muse, mutect2
- APOB | c.4582C>T p.Q1528* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99267387; called by muse, mutect2, varscan2
- AQP10 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100270449; called by muse, mutect2, varscan2
- AREL1 | c.857del p.R286Pfs*8 | Frame Shift Del (DEL) | VAF 83/304 reads (27%) | catalogued as COSV62666333; called by mutect2, pindel, varscan2
- ARHGAP18 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV100936433; called by muse, mutect2, varscan2
- ARHGAP4 | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 81/121 reads (67%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.45); catalogued as COSV100604197; called by muse, mutect2, varscan2
- ARHGEF18 | c.550G>A p.A184T (on ENST00000359920 / NM_001130955.2; = p.A80T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100149537, COSV100149932; called by muse, mutect2, varscan2
- ARID2 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 98/169 reads (58%) | catalogued as COSV100536842; called by muse, mutect2, varscan2
- ARL14EP | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99956024; called by muse, mutect2, varscan2
- ASAP1 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100727696; called by muse, mutect2, varscan2
- ASPM | c.10331G>T p.R3444I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs751974149, COSV99660953; called by muse, mutect2, varscan2
- ASPRV1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100208350; called by muse, mutect2, varscan2
- ASTN1 | c.3375G>T p.W1125C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62492952, COSV62499991; called by muse, mutect2, varscan2
- ASTN1 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as rs768929252, COSV99922769; called by muse, mutect2, varscan2
- ASXL1 | c.1286A>G p.E429G | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100040855; called by muse, mutect2, varscan2
- ATAD2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54883461; called by muse, mutect2
- ATAD2 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99785153; called by muse, mutect2
- ATG2A | c.3207G>C p.L1069F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101034727; called by muse, mutect2
- ATP2A2 | c.2196G>T p.M732I | Missense Mutation (SNP) | VAF 93/138 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs756804449, COSV100428845; called by muse, mutect2, varscan2
- ATP7A | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 95/148 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100431493; called by muse, mutect2, varscan2
- ATP7A | c.4304G>A p.S1435N | Missense Mutation (SNP) | VAF 135/206 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100431495; called by muse, mutect2, varscan2
- ATP8B2 | c.2974G>C p.A992P (on ENST00000672630; = p.A959P on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100528185; called by muse, mutect2, varscan2
- ATP8B4 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467055; called by muse, mutect2, varscan2
- ATRX | c.1150A>T p.S384C | Missense Mutation (SNP) | VAF 133/207 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100971297; called by muse, mutect2, varscan2
- ATXN2L | c.2222A>T p.Q741L | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100294992; called by mutect2, varscan2
- B3GNT2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57344563, COSV57345487; called by muse, mutect2, varscan2
- B3GNT5 | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100193677; called by muse, mutect2, varscan2
- BARD1 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs876658147, COSV99639650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCLAF3 | c.1584G>T p.L528F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100503385; called by muse, mutect2, varscan2
- BFSP2 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100183893; called by muse, mutect2, varscan2
- BICC1 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99570829; called by muse, mutect2, varscan2
- BICD2 | c.2163G>T p.M721I | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100794275; called by muse, mutect2, varscan2
- BICD2 | c.2162T>A p.M721K | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100794277; called by muse, mutect2, varscan2
- BIN2 | c.1175G>C p.R392P | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV57204685, COSV99909651; called by muse, mutect2, varscan2
- BMP7 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101216214, COSV67781678; called by muse, mutect2, varscan2
- BPI | c.704G>C p.G235A (on ENST00000262865; = p.G231A on NM_001725.3) | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99480902; called by muse, mutect2, varscan2
- BPTF | c.6093G>C p.E2031D | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100075814; called by muse, mutect2, varscan2
- BRD9 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 29/186 reads (16%) | catalogued as COSV100057495, COSV60245300; called by muse, mutect2, varscan2
- BRPF3 | c.3212G>A p.R1071H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs370467092; called by muse, mutect2, varscan2
- BRWD1 | c.5092C>T p.Q1698* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100313932; called by muse, mutect2, varscan2
- BTBD9 | c.1210G>C p.A404P | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100022524; called by muse, mutect2, varscan2
- BTN2A2 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.107); catalogued as COSV100760576, COSV61856804; called by muse, mutect2, varscan2
- BUB1B | c.1949A>T p.E650V | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV99807210; called by muse, mutect2, varscan2
- C11orf87 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100535879; called by muse, mutect2, varscan2
- C1QC | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101009533, COSV101009575; called by muse, mutect2, varscan2
- C1orf127 | c.1945A>T p.S649C | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100983506; called by muse, mutect2, varscan2
- C1orf141 | c.471A>T p.R157S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as COSV100924377; called by mutect2, varscan2
- C1orf94 | c.1663del p.R555Efs*5 (on ENST00000488417 / NM_001134734.2; = p.R365Efs*5 on NM_032884.5) | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as rs762299922; called by mutect2, pindel, varscan2
- C22orf42 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1315652954, COSV101173371; called by muse, mutect2, varscan2
- C2orf78 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.251); catalogued as COSV101281023; called by muse, mutect2, varscan2
- C5AR2 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV99953878; called by muse, mutect2, varscan2
- C5orf58 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as COSV50475120; called by muse, mutect2, varscan2
- C7orf26 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100254046; called by muse, mutect2
- C8B | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as COSV100980878; called by muse, mutect2, varscan2
- CACNA1A | c.4738G>T p.A1580S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV100803072, COSV64197125; called by muse, mutect2, varscan2
- CACNA1B | c.4830C>A p.F1610L | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99499246; called by muse, mutect2, varscan2
- CACNA1E | c.493T>A p.F165I | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100704306, COSV100704704; called by muse, mutect2, varscan2
- CACNA1I | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100361280; called by muse, mutect2, varscan2
- CACNB2 | c.1516C>T p.R506C (on ENST00000324631 / NM_201596.3; = p.R451C on NM_000724.4) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as rs111250176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50063933, COSV99136976; called by muse, mutect2, varscan2
- CALB1 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55368888; called by muse, mutect2
- CALCRL | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV101131031; called by muse, mutect2, varscan2
- CAMK2B | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV99323412; called by muse, mutect2, varscan2
- CAPN5 | c.1977G>T p.Q659H (on ENST00000456580; = p.Q619H on NM_004055.5) | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.336); catalogued as COSV99582471; called by muse, mutect2, varscan2
- CASS4 | c.1990C>A p.Q664K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV100824874; called by muse, mutect2, varscan2
- CATSPER1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV100376196; called by muse, mutect2
- CATSPERD | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV101062759; called by muse, mutect2
- CCAR2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.331); catalogued as COSV100414902; called by muse, mutect2
- CCDC134 | c.493-2A>T p.X165_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99740809; called by muse, mutect2, varscan2
- CCDC141 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as COSV99837314; called by muse, mutect2, varscan2
- CCDC148 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99321275; called by muse, mutect2, varscan2
- CCDC54 | c.231A>T p.Q77H | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99660307; called by muse, mutect2, varscan2
- CCDC54 | c.475del p.E159Rfs*21 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | catalogued as rs1166441911; called by mutect2, pindel, varscan2
- CCDC87 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100040130; called by muse, mutect2, varscan2
- CCZ1 | c.513C>A p.F171L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100382777; called by muse, mutect2, varscan2
- CD163 | c.3325G>T p.D1109Y | Missense Mutation (SNP) | VAF 96/153 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100776008, COSV100776076; called by muse, mutect2, varscan2
- CD300LB | c.150C>A p.C50* | Nonsense Mutation (SNP) | VAF 61/348 reads (18%) | catalogued as COSV100075418, COSV58726996; called by muse, mutect2, varscan2
- CDAN1 | c.3532A>G p.S1178G | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99314556; called by muse, mutect2, varscan2
- CDC42BPG | c.1913T>A p.L638Q | Missense Mutation (SNP) | VAF 151/562 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100712141; called by muse, mutect2, varscan2
- CDCP1 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99944248; called by muse, mutect2, varscan2
- CDH10 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.348); catalogued as COSV52594907; called by muse, mutect2, varscan2
- CDH12 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 170/253 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203218, COSV66392701; called by muse, mutect2, varscan2
- CDH24 | c.1370G>T p.S457I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs771578171, COSV99944159; called by muse, mutect2
- CDH6 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99420528; called by muse, mutect2, varscan2
- CDH8 | c.2121G>T p.M707I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100183771; called by muse, mutect2, varscan2
- CDHR2 | c.2053G>T p.V685L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99992085; called by muse, mutect2, varscan2
- CDR1 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100983444, COSV65163967; called by muse, mutect2, varscan2
- CENPE | c.4427A>T p.E1476V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99478876; called by muse, mutect2
- CENPF | c.9041G>T p.R3014L | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1279276694, COSV100871904; called by muse, mutect2, varscan2
- CENPI | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 190/294 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99515742; called by muse, mutect2, varscan2
- CENPU | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV99860096; called by muse, mutect2, varscan2
- CEP128 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV99825720; called by muse, mutect2, varscan2
- CEP164 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV99634161; called by muse, mutect2, varscan2
- CERK | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99348766; called by muse, mutect2, varscan2
- CFAP44 | c.111A>T p.Q37H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99870235; called by muse, mutect2, varscan2
- CFAP46 | c.7398G>T p.Q2466H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99585402; called by muse, mutect2, varscan2
- CFAP47 | c.1798C>G p.H600D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99935689; called by muse, mutect2, varscan2
- CFAP54 | c.4732G>T p.D1578Y | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100733297; called by muse, mutect2, varscan2
- CFHR3 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100807722; called by muse, mutect2, varscan2
- CFLAR | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs939551530, COSV100009794; called by muse, mutect2, varscan2
- CHAF1B | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100023731; called by muse, mutect2, varscan2
- CHAT | c.378T>A p.S126R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV100340741, COSV60334789; called by muse, mutect2, varscan2
- CHGB | c.190+2T>A p.X64_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100973062; called by muse, mutect2, varscan2
- CHRDL1 | c.998G>A p.G333D (on ENST00000372045; = p.G339D on NM_145234.4) | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54326801; called by muse, mutect2, varscan2
- CHRDL1 | c.748C>A p.H250N (on ENST00000372045; = p.H256N on NM_145234.4) | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99488601; called by muse, mutect2, varscan2
- CHRM3 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV55087647; called by muse, mutect2, varscan2
- CHRNA1 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99650668; called by muse, mutect2, varscan2
- CHRNA3 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs762042374, COSV100468568; called by muse, mutect2, varscan2
- CHSY1 | c.1015G>T p.V339F | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.506); catalogued as COSV99574175; called by muse, mutect2, varscan2
- CILP2 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99365089; called by muse, mutect2, varscan2
- CLCA1 | c.1680G>A p.K560= | Splice Region (SNP) | VAF 14/36 reads (39%) | catalogued as COSV52329121, COSV99322726; called by muse, mutect2, varscan2
- CLCA2 | c.792C>G p.N264K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100991676; called by muse, mutect2, varscan2
- CLCA2 | c.1370C>A p.S457* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100991677; called by muse, mutect2, varscan2
- CLCN1 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100578426, COSV58372920; called by muse, mutect2, varscan2
- CLCN1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1313398, COSV100578428; called by muse, mutect2, varscan2
- CLCN3 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100641812; called by muse, mutect2, varscan2
- CLDN11 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.453); catalogued as COSV99291115; called by muse, mutect2, varscan2
- CLDN16 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 71/199 reads (36%) | catalogued as COSV99290337; called by muse, mutect2, varscan2
- CLDN2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 83/118 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV100390159; called by muse, mutect2, varscan2
- CLEC14A | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100643654, COSV60561542; called by muse, mutect2, varscan2
- CLHC1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100811493; called by muse, mutect2, varscan2
- CLIP4 | c.530-2A>T p.X177_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100192325; called by muse, mutect2, varscan2
- CLNK | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99905687; called by muse, mutect2, varscan2
- CLSTN2 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101515883, COSV71724838; called by muse, mutect2, varscan2
- CMPK2 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1179796870, COSV99878995; called by muse, mutect2, varscan2
- CMYA5 | c.7843G>C p.V2615L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.164); catalogued as COSV101484297; called by muse, mutect2, varscan2
- CNRIP1 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55148977; called by muse, mutect2, varscan2
- CNTF | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV100284700; called by muse, mutect2, varscan2
- CNTNAP5 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101443992; called by muse, varscan2
- CNTNAP5 | c.3809G>T p.R1270L | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV101443993, COSV104436460; called by muse, mutect2, varscan2
- COG5 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99772951; called by muse, mutect2, varscan2
- COL11A1 | c.2282C>A p.P761H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100617865, COSV62171984; called by muse, mutect2, varscan2
- COL11A2 | c.5006C>A p.A1669D (on ENST00000341947 / NM_080680.3; = p.A1562D on NM_080679.2) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); catalogued as COSV100554425; called by muse, mutect2, varscan2
- COL11A2 | c.3851G>T p.R1284L (on ENST00000341947 / NM_080680.3; = p.R1177L on NM_080679.2) | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); catalogued as COSV100554427; called by muse, mutect2, varscan2
- COL12A1 | c.3671G>T p.R1224L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100486362; called by muse, mutect2, varscan2
- COL15A1 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100897922; called by muse, mutect2, varscan2
- COL18A1 | c.1591C>G p.Q531E (on ENST00000359759 / NM_130444.3; = p.Q296E on NM_030582.4) | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100700910; called by muse, mutect2, varscan2
- COL21A1 | c.2761C>A p.H921N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.122); catalogued as COSV99779831; called by muse, mutect2, varscan2
- COL2A1 | c.1267-1G>T p.X423_splice | Splice Site (SNP) | VAF 30/48 reads (63%) | catalogued as COSV100477279, COSV61529656; called by muse, mutect2, varscan2
- COL3A1 | c.2338G>A p.G780S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100483616, COSV58593001; called by muse, mutect2, varscan2
- COL4A1 | c.2618G>C p.G873A | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101011472; called by muse, mutect2, varscan2
- COL4A3 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.429); catalogued as COSV101170502; called by muse, mutect2, varscan2
- COL4A5 | c.2860C>A p.P954T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1368083515, COSV100089367; called by muse, mutect2, varscan2
- COL4A5 | c.2861C>A p.P954Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100089373; called by muse, mutect2, varscan2
- COL5A1 | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100880444; called by muse, mutect2, varscan2
- COL5A1 | c.4879C>T p.R1627W | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as rs558906147, COSV65664816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.1456G>T p.G486W | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880686; called by muse, mutect2, varscan2
- COL5A2 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100880687; called by muse, mutect2, varscan2
- COL5A3 | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53421472; called by muse, mutect2, varscan2
- COL6A3 | c.9116C>A p.T3039K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV55093957; called by muse, mutect2, varscan2
- COL6A3 | c.4488G>T p.Q1496H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99800700; called by muse, varscan2
- COPG2 | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV100449707; called by muse, mutect2, varscan2
- COPZ1 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 195/346 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100017696; called by muse, mutect2, varscan2
- COQ8A | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100825792; called by muse, mutect2
- CORO1B | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100396722, COSV58173358; called by muse, mutect2, varscan2
- COX7A2L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs781228176, COSV99310044; called by muse, mutect2
- CPN2 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100103249; called by muse, mutect2, varscan2
- CPNE7 | c.1823A>T p.E608V | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV99255060; called by muse, mutect2, varscan2
- CPSF6 | c.1254G>T p.M418I | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV57015013, COSV99879646; called by muse, mutect2, varscan2
- CPXM1 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV101013815; called by muse, mutect2, varscan2
- CRISP1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs759917401, COSV100237064; called by muse, mutect2, varscan2
- CRYGD | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100006120; called by muse, mutect2, varscan2
- CSF1R | c.2192C>A p.T731N | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as rs774848316, COSV99642811; called by muse, mutect2, varscan2
- CSHL1 | c.332T>A p.L111Q (on ENST00000309894 / NM_022581.3; = p.L17Q on NM_001318.4) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV99368147; called by muse, mutect2, varscan2
- CSMD1 | c.302G>T p.R101I | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101224162; called by muse, mutect2, varscan2
- CSMD2 | c.8612C>A p.S2871* | Nonsense Mutation (SNP) | VAF 40/98 reads (41%) | catalogued as COSV99594191; called by muse, mutect2, varscan2
- CSMD2 | c.4480C>A p.P1494T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99594192; called by muse, varscan2
- CSMD3 | c.7958G>C p.R2653P (on ENST00000297405 / NM_001363185.1; = p.R2549P on NM_052900.3) | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV99844002, COSV99844666; called by muse, mutect2, varscan2
- CSMD3 | c.4166del p.G1389Efs*8 (on ENST00000297405 / NM_001363185.1; = p.G1285Efs*8 on NM_052900.3) | Frame Shift Del (DEL) | VAF 26/195 reads (13%) | catalogued as COSV52251070; called by mutect2, pindel, varscan2
- CSMD3 | c.2213C>G p.P738R (on ENST00000297405 / NM_001363185.1; = p.P634R on NM_052900.3) | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844667; called by muse, mutect2, varscan2
- CSMD3 | c.1471G>T p.E491* (on ENST00000297405 / NM_001363185.1; = p.E387* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 21/180 reads (12%) | catalogued as COSV52165514, COSV99844673; called by muse, mutect2, varscan2
- CSTF2T | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV100484298; called by muse, mutect2, varscan2
- CT55 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99358961; called by muse, mutect2, varscan2
- CTCFL | c.1547G>T p.C516F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99713188; called by muse, mutect2, varscan2
- CTNNA3 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as COSV101041554; called by muse, mutect2, varscan2
- CWH43 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV56940178, COSV99893897; called by muse, mutect2, varscan2
- CYP27C1 | c.640T>A p.L214I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV100079992; called by muse, mutect2, varscan2
- CYP2A13 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100386983; called by muse, varscan2
- CYP3A7 | c.1391_1393del p.S464del | In Frame Del (DEL) | VAF 17/177 reads (10%) | catalogued as rs1337875866; called by mutect2, pindel, varscan2
- CYREN | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99313297; called by muse, mutect2, varscan2
- DACT1 | c.2308A>G p.S770G | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1051348574, COSV100242080; called by muse, mutect2, varscan2
- DAG1 | c.1690C>T p.L564F | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as COSV100445139; called by muse, mutect2, varscan2
- DAGLB | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV99766108; called by muse, mutect2
- DCAF1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 125/198 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV100244844; called by muse, mutect2, varscan2
- DCAF6 | c.1549G>T p.G517C (on ENST00000312263 / NM_001349778.1; = p.G537C on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.376); catalogued as COSV100394725; called by muse, mutect2, varscan2
- DCSTAMP | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760724223, COSV52576948, COSV99886396, COSV99886886; called by muse, mutect2
- DDX50 | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV101007301; called by muse, mutect2, varscan2
- DENND2A | c.2692G>T p.V898L | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV99326833; called by muse, mutect2, varscan2
- DENND2D | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100718786, COSV62959486; called by muse, mutect2, varscan2
- DERA | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101397482; called by muse, mutect2, varscan2
- DEUP1 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV99977542; called by muse, mutect2, varscan2
- DGKD | c.2086C>G p.L696V (on ENST00000264057 / NM_152879.3; = p.L652V on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99897340; called by muse, mutect2
- DGKI | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99936776; called by muse, mutect2, varscan2
- DGKK | c.1561G>T p.V521L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1557225746, COSV101053173; called by muse, mutect2, varscan2
- DHX8 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 89/358 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV52253345, COSV99292550; called by muse, mutect2, varscan2
- DHX8 | c.3346G>T p.A1116S | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV99292564; called by muse, mutect2, varscan2
- DIO3 | c.864G>T p.W288C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100832235; called by muse, mutect2, varscan2
- DIP2A | c.4366G>T p.G1456W | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596247; called by muse, mutect2, varscan2
- DISP3 | c.3196G>T p.V1066L | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99609756; called by muse, mutect2, varscan2
- DLEC1 | c.714T>A p.C238* | Nonsense Mutation (SNP) | VAF 44/68 reads (65%) | catalogued as COSV100343243; called by muse, mutect2, varscan2
- DLG5 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV100967796; called by muse, mutect2, varscan2
- DLGAP1 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100228087, COSV100233125; called by muse, mutect2, varscan2
- DMBX1 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV100760870; called by muse, mutect2, varscan2
- DMXL1 | c.8836G>A p.G2946R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224776; called by muse, mutect2, varscan2
- DMXL2 | c.3046G>T p.V1016F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99198373; called by muse, mutect2, varscan2
- DNAAF1 | c.1172C>A p.P391Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533811; called by muse, mutect2
- DNER | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100519863; called by muse, mutect2, varscan2
- DNM3 | c.1987C>T p.R663C (on ENST00000355305 / NM_001350206.2; = p.R657C on NM_015569.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs756468578, COSV62453812; called by muse, mutect2, varscan2
- DOCK10 | c.2976C>A p.F992L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99291124; called by muse, mutect2
- DOCK10 | c.1174A>T p.K392* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99291129; called by muse, mutect2, varscan2
- DOCK2 | c.5041G>T p.E1681* | Nonsense Mutation (SNP) | VAF 69/140 reads (49%) | catalogued as COSV99914632; called by muse, mutect2, varscan2
- DOCK2 | c.5129C>A p.A1710E | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.185); catalogued as rs200684209, COSV99914633; called by muse, mutect2, varscan2
- DOCK4 | c.1903G>T p.G635W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867053774, COSV101447951; called by muse, mutect2
- DOCK4 | c.938C>G p.T313R | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101455692; called by muse, mutect2, varscan2
- DOK6 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.674); catalogued as COSV101234906; called by muse, mutect2, varscan2
- DOK6 | c.579G>T p.W193C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV101234907, COSV66926316; called by muse, mutect2, varscan2
- DOP1B | c.5969A>T p.H1990L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV101215745; called by muse, mutect2, varscan2
- DPP6 | c.1649T>G p.F550C (on ENST00000377770 / NM_001364500.2; = p.F488C on NM_001936.5) | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100127577; called by muse, mutect2, varscan2
- DPYD | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs72549304, CM024470, COSV64594416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRC1 | c.2178A>T p.E726D | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99718693; called by muse, mutect2, varscan2
- DRD2 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100670057, COSV60763677; called by muse, mutect2, varscan2
- DRD2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201724929, COSV60762454; called by muse, mutect2, varscan2
- DRD3 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV55682181, COSV99879645; called by muse, mutect2, varscan2
- DSC1 | c.2584G>T p.V862L | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); catalogued as COSV99938136; called by muse, mutect2, varscan2
- DSG3 | c.1649T>A p.L550H | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.614); catalogued as COSV99934621; called by muse, mutect2, varscan2
- DSG4 | c.1750T>G p.L584V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.151); catalogued as COSV100356320; called by muse, mutect2
- DST | c.22108C>T p.R7370* (on ENST00000361203 / NM_001374722.1; = p.R5080* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54996198; called by muse, mutect2, varscan2
- DST | c.20029G>T p.D6677Y (on ENST00000361203 / NM_001374722.1; = p.D4374Y on NM_015548.5) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99759185; called by muse, mutect2, varscan2
- DST | c.15802C>T p.R5268* (on ENST00000361203 / NM_001374722.1; = p.R2856* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99759190; called by muse, mutect2, varscan2
- DUSP4 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99530013; called by muse, mutect2, varscan2
- EDA2R | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99490910; called by muse, mutect2, varscan2
- EDIL3 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV56895464, COSV99678643; called by muse, mutect2, varscan2
- EEF2 | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV100500940; called by muse, mutect2, varscan2
- EEPD1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99632898; called by muse, mutect2, varscan2
- EHD3 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100434837; called by muse, mutect2, varscan2
- EHD3 | c.1174del p.Q392Sfs*5 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as COSV100434563; called by mutect2, pindel, varscan2
- EHMT2 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV100977237, COSV64997154; called by muse, mutect2, varscan2
- ELANE | c.98del p.G33Afs*27 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV52256221; called by pindel, varscan2
- ELAPOR1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64044918, COSV64045626; called by muse, mutect2, varscan2
- ELAPOR1 | c.2804A>G p.Q935R | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100884472; called by muse, mutect2, varscan2
- ELAVL3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99371871; called by muse, mutect2, varscan2
- ELL2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99427819; called by muse, mutect2, varscan2
- ELOVL4 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876130, COSV100876381; called by muse, mutect2, varscan2
- EML5 | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100716095; called by muse, mutect2, varscan2
- EMX1 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV99252591; called by muse, mutect2, varscan2
- ENPP1 | c.1555_1556insG p.Q519Rfs*20 | Frame Shift Ins (INS) | VAF 120/350 reads (34%) | catalogued as COSV100719628; called by pindel, varscan2
- ENTPD6 | c.494A>T p.Q165L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV100737159; called by muse, mutect2
- ENTPD8 | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395690; called by muse, mutect2, varscan2
- EPB41L1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV99151457; called by muse, mutect2
- EPHA7 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as rs1402331883, COSV100994200, COSV65194736; called by muse, mutect2, varscan2
- EPHA7 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs1286516366, COSV65170326; called by muse, mutect2, varscan2
- EPHA8 | c.2290C>A p.R764S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385514; called by muse, mutect2, varscan2
- EPHB2 | c.2397G>T p.Q799H (on ENST00000400191 / NM_001309193.2; = p.Q800H on NM_004442.7) | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101007342, COSV65865560; called by muse, mutect2, varscan2
- EPHB3 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV100383239; called by muse, mutect2, varscan2
- EPHB6 | c.1412G>C p.S471T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs772331271, COSV100844405, COSV63891302; called by muse, mutect2, varscan2
- EPHX1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs752393079, COSV99689079, COSV99689168; called by muse, mutect2, varscan2
- EPN1 | c.1407G>T p.K469N (on ENST00000270460 / NM_001321263.1; = p.K443N on NM_013333.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99322275; called by muse, mutect2
- EPRS1 | c.1349G>T p.W450L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859472; called by muse, mutect2, varscan2
- EPYC | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664866; called by muse, mutect2, varscan2
- ERI3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100952231; called by muse, mutect2, varscan2
- ESRRB | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99835662; called by muse, mutect2, varscan2
- F11 | c.1556G>C p.W519S | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201007090, CM002952, COSV99250896; called by muse, mutect2, varscan2
- FABP9 | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100986953, COSV66911430; called by muse, mutect2, varscan2
- FAM107B | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV99474329; called by muse, mutect2, varscan2
- FAM114A1 | c.1670G>T p.S557I | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100729463; called by muse, mutect2, varscan2
- FAM120A | c.1013A>T p.H338L | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.215); catalogued as COSV99466427; called by muse, mutect2, varscan2
- FAM131A | c.556G>C p.G186R (on ENST00000310585; = p.G217R on NM_144635.5) | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV99658928; called by muse, mutect2, varscan2
- FAM135B | c.3493G>A p.G1165R | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424183; called by muse, mutect2
- FAM166C | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99995034; called by muse, mutect2, varscan2
- FAM171B | c.2003C>G p.P668R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1001995359, COSV100488911, COSV59001534; called by muse, mutect2, varscan2
- FAM171B | c.2450G>T p.R817L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs779463113, COSV100488913, COSV59001270; called by muse, mutect2, varscan2
- FAM181A | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV50891525; called by muse, mutect2, varscan2
- FAM47A | c.1556C>A p.S519* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100650027, COSV60495344; called by muse, varscan2
- FAM83D | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99465444; called by muse, mutect2, varscan2
- FANCF | c.347T>C p.F116S | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV100541888; called by muse, mutect2, varscan2
- FANCM | c.1788+1G>T p.X596_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99950548, COSV99951527; called by muse, mutect2
- FARP2 | c.222G>C p.W74C | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.911); catalogued as COSV99885316; called by muse, mutect2, varscan2
- FARSB | c.60T>G p.T20= | Splice Region (SNP) | VAF 12/117 reads (10%) | catalogued as COSV99918584; called by muse, mutect2
- FASN | c.4261A>T p.S1421C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV100148241; called by muse, mutect2, varscan2
- FAT1 | c.8496G>T p.R2832S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV101499591; called by muse, mutect2, varscan2
- FAT1 | c.4726G>A p.A1576T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV101499592; called by muse, mutect2, varscan2
- FAT3 | c.3253G>C p.G1085R | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53147085, COSV99969880; called by muse, mutect2, varscan2
- FAT3 | c.8920G>T p.A2974S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV99969883; called by muse, mutect2, varscan2
- FBLN1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV99411278; called by muse, mutect2, varscan2
- FBN2 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV99330054; called by muse, mutect2, varscan2
- FBN2 | c.783C>G p.C261W | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99330058; called by muse, mutect2, varscan2
- FBN3 | c.2374G>T p.G792C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99561644; called by muse, mutect2, varscan2
- FBXO40 | c.226A>T p.M76L | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs779072550, COSV100573283; called by muse, mutect2, varscan2
- FBXW2 | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100535286; called by muse, mutect2, varscan2
- FCGR3A | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as COSV100914699; called by muse, mutect2, varscan2
- FCN1 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.549); catalogued as COSV65661900; called by muse, mutect2, varscan2
- FCRL1 | c.616T>G p.S206A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV100839877; called by muse, mutect2, varscan2
- FCRL2 | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100829987; called by muse, mutect2, varscan2
- FDX1 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99501923; called by muse, mutect2, varscan2
- FER | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as COSV99813748; called by muse, mutect2, varscan2
- FGL2 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs751515083, COSV99593032; called by muse, mutect2, varscan2
- FHL5 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100459682; called by muse, mutect2, varscan2
- FIBP | c.469del p.D157Tfs*38 | Frame Shift Del (DEL) | VAF 54/194 reads (28%) | catalogued as COSV57033693; called by mutect2, pindel, varscan2
- FIGNL1 | c.1703del p.P568Qfs*9 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as COSV63553890; called by mutect2, varscan2
- FKBPL | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100913601; called by muse, mutect2, varscan2
- FKTN | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs142783718, COSV99795546; called by muse, mutect2, varscan2
- FLG | c.1607T>C p.V536A | Missense Mutation (SNP) | VAF 148/706 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.082); catalogued as COSV100912008, COSV104425335; called by muse, mutect2, varscan2
- FLNB | c.1954G>T p.G652W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914423; called by muse, mutect2, varscan2
- FLNC | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368615, COSV100369000; called by muse, mutect2, varscan2
- FLNC | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 89/166 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs377587489, COSV100368616; called by muse, mutect2, varscan2
- FLNC | c.6049G>T p.V2017L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV100368458, COSV57966956; called by muse, mutect2, varscan2
- FMNL1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs370784492; called by muse, mutect2, varscan2
- FNDC1 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV99796514; called by muse, mutect2, varscan2
- FNDC1 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV99796517; called by muse, mutect2, varscan2
- FNDC1 | c.3890C>A p.S1297Y | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1162465975, COSV99796519; called by muse, mutect2, varscan2
- FOCAD | c.2177A>G p.H726R | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1198793529, COSV100620655; called by muse, mutect2, varscan2
- FOLH1 | c.1553G>C p.G518A | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV57051921, COSV99923753; called by muse, mutect2, varscan2
- FOLH1 | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 46/175 reads (26%) | catalogued as COSV99923756; called by muse, mutect2, varscan2
- FRAS1 | c.2018G>T p.C673F | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355174; called by muse, mutect2, varscan2
- FRAS1 | c.11763G>C p.L3921F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as COSV99355181; called by muse, mutect2, varscan2
- FREM2 | c.8591A>T p.Y2864F | Missense Mutation (SNP) | VAF 106/183 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99750373; called by muse, mutect2, varscan2
- FRMD4B | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV101273647; called by muse, mutect2, varscan2
- FSTL5 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100059964; called by muse, mutect2, varscan2
- FUBP1 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs773565597, COSV99629465; called by muse, mutect2
- FUT10 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV59660053; called by muse, mutect2, varscan2
- FUT10 | c.1388G>T p.R463M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100567264, COSV59660062; called by muse, mutect2, varscan2
- G2E3 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs773921960, COSV99249850; called by muse, mutect2, varscan2
- GAB1 | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53756562; called by muse, mutect2, varscan2
- GAB4 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV101272082; called by muse, mutect2, varscan2
- GABBR2 | c.1270G>C p.G424R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52311262, COSV99411191; called by muse, mutect2, varscan2
- GABRA4 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99974528; called by muse, mutect2, varscan2
- GABRG1 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV99777653; called by muse, mutect2, varscan2
- GABRG1 | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV99778590; called by muse, mutect2, varscan2
- GAL3ST1 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100143208; called by muse, mutect2, varscan2
- GALNT13 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.916); catalogued as COSV101224067, COSV67235422; called by muse, mutect2, varscan2
- GALNT13 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101224069; called by muse, mutect2, varscan2
- GALNT14 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV61102355, COSV61103649; called by muse, mutect2, varscan2
- GAP43 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100525667, COSV100525884; called by muse, mutect2, varscan2
- GATA4 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633001; called by muse, mutect2, varscan2
- GBA3 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.632); catalogued as COSV101545553; called by muse, mutect2, varscan2
- GBP7 | c.689A>T p.K230I | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99643400; called by muse, mutect2, varscan2
- GCN1 | c.427-2A>T p.X143_splice | Splice Site (SNP) | VAF 27/43 reads (63%) | catalogued as COSV100325862, COSV56104041; called by muse, mutect2, varscan2
- GCNT1 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100946634, COSV65059030; called by muse, mutect2, varscan2
- GDAP2 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.946); catalogued as rs1287479686, COSV101032138; called by muse, mutect2, varscan2
- GEN1 | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438150; called by muse, mutect2, varscan2
- GHR | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV100051778; called by muse, mutect2
- GIGYF1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99309880; called by muse, mutect2, varscan2
- GIGYF2 | c.3152C>G p.T1051S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV101004584; called by muse, mutect2, varscan2
- GIMAP2 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV99785499; called by muse, mutect2, varscan2
- GIMAP6 | c.671G>T p.W224L | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV100188359; called by muse, mutect2, varscan2
- GJC3 | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100458493, COSV57210751; called by muse, mutect2, varscan2
- GLI2 | c.4094G>A p.R1365H (on ENST00000361492 / NM_001374353.1; = p.R1382H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs200080112; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLRB | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100030071, COSV52416446; called by muse, mutect2, varscan2
- GLYATL2 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1217238835, COSV54849720; called by muse, mutect2, varscan2
- GOLGA3 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 168/249 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs774878722, COSV52627844; called by muse, mutect2, varscan2
- GOLGB1 | c.3917A>G p.Q1306R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as rs201705247, COSV100511406; called by muse, mutect2, varscan2
- GPATCH2L | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99833870; called by muse, mutect2, varscan2
- GPR141 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs371535293; called by muse, mutect2, varscan2
- GPR152 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100351630; called by muse, mutect2, varscan2
- GPR174 | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99338342; called by muse, mutect2, varscan2
- GRAMD1C | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100822963; called by muse, mutect2, varscan2
- GRB10 | c.972G>T p.K324N (on ENST00000398812; = p.K266N on NM_001001550.3) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100240942; called by muse, mutect2, varscan2
- GRB7 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as COSV100485634; called by muse, mutect2
- GRID1 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1427231614, COSV60057886; called by muse, mutect2, varscan2
- GRIK2 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59713176; called by muse, mutect2, varscan2
- GRIN2B | c.3694C>G p.Q1232E | Missense Mutation (SNP) | VAF 75/127 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.154); catalogued as COSV101663158; called by muse, mutect2, varscan2
- GRIN2D | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99616854; called by muse, mutect2, varscan2
- GRM1 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51188249; called by muse, mutect2, varscan2
- GRM5 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100553964; called by muse, mutect2, varscan2
- GTPBP1 | c.254G>T p.R85M | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV99323445; called by muse, mutect2, varscan2
- GUCY1A1 | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1256580863, COSV99638399; called by muse, mutect2, varscan2
- GXYLT2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs200557116, COSV67473873; called by muse, mutect2, varscan2
- H2BC6 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs767620801, COSV100534489, COSV61591721; called by muse, mutect2, varscan2
- H3C4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV61911648, COSV61911890; called by muse, mutect2, varscan2
- HABP2 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100668069; called by muse, mutect2, varscan2
- HBB | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58942981; called by muse, mutect2, varscan2
- HBE1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV99496384; called by muse, mutect2, varscan2
- HCN1 | c.1636A>T p.K546* | Nonsense Mutation (SNP) | VAF 92/164 reads (56%) | catalogued as COSV100301808; called by muse, varscan2
- HCN1 | c.340T>A p.F114I | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100301813; called by muse, mutect2, varscan2
- HDAC9 | c.2931G>A p.L977= | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101287079; called by muse, mutect2, varscan2
- HERC2 | c.14458del p.D4820Tfs*12 | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | catalogued as COSV55316552; called by mutect2, pindel, varscan2
- HERC5 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs1460300756, COSV99988096; called by muse, mutect2, varscan2
- HEXA | c.1432G>T p.G478W | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM125499, COSV99173829; called by muse, mutect2, varscan2
- HGF | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV99738193; called by muse, mutect2, varscan2
- HIPK3 | c.1577A>G p.N526S | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100306007; called by muse, mutect2, varscan2
- HIVEP3 | c.1837A>T p.T613S | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99913671; called by muse, mutect2, varscan2
- HJURP | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs201325476, COSV101366408; called by muse, mutect2, varscan2
- HMGCS1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100285053; called by muse, mutect2, varscan2
- HNRNPAB | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100359602; called by muse, mutect2, varscan2
- HOOK3 | c.1620T>C p.D540= | Splice Region (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100295882; called by muse, mutect2, varscan2
- HOXA11 | c.410C>A p.P137Q | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99136093; called by muse, mutect2, varscan2
- HOXA3 | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100415537, COSV100415645; called by muse, mutect2, varscan2
- HOXA5 | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99762452; called by muse, mutect2, varscan2
- HOXA6 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99762453, COSV99762499; called by muse, mutect2, varscan2
- HOXB4 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV100203645, COSV100203831; called by muse, mutect2, varscan2
- HOXB6 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV99494700; called by muse, mutect2, varscan2
- HOXC12 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 125/209 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751862154, COSV54534655; called by muse, mutect2, varscan2
- HOXD9 | c.1058G>T p.*353Lext*56 | Nonstop Mutation (SNP) | VAF 45/128 reads (35%) | catalogued as COSV50897934; called by muse, mutect2, varscan2
- HRH1 | c.66G>T p.M22I | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101229101; called by muse, mutect2, varscan2
- HRH3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs377382211; called by muse, mutect2, varscan2
- HRNR | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs747884891, COSV100913846, COSV64255415; called by muse, mutect2
- HS3ST5 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100451279; called by muse, mutect2, varscan2
- HSPA1L | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV100989448; called by muse, mutect2, varscan2
- HSPA1L | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100989449; called by muse, mutect2, varscan2
- HTR1E | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV100541258, COSV59507135; called by muse, mutect2, varscan2
- HTR6 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV99230409; called by muse, mutect2, varscan2
- HTRA4 | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV100205900; called by muse, mutect2, varscan2
- ICE1 | c.1859A>C p.D620A | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.058); catalogued as COSV99665491; called by muse, mutect2, varscan2
- IGF2 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV100324204, COSV56097224, COSV56099937; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs1233864594; called by muse, mutect2, varscan2
- IGKV1-16 | c.255C>G p.S85R | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs759228948; called by muse, mutect2, varscan2
- IL1RAPL2 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100781850; called by muse, mutect2, varscan2
- IL27 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100112835; called by muse, mutect2, varscan2
- IQCN | c.2610G>T p.E870D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV101148969; called by muse, mutect2, varscan2
- IQGAP2 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV57184355; called by muse, mutect2, varscan2
- IRGC | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV99746492; called by muse, mutect2, varscan2
- ITGAX | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99191977; called by muse, mutect2, varscan2
- ITGAX | c.2504G>A p.G835D | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.313); catalogued as COSV99191979; called by muse, mutect2, varscan2
- ITGAX | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs746029786, COSV99191980; called by muse, mutect2, varscan2
- ITIH4 | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV99819780; called by muse, mutect2, varscan2
- ITM2A | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 61/85 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs1034925279, COSV64810552; called by muse, mutect2, varscan2
- ITPR2 | c.3410A>T p.E1137V | Missense Mutation (SNP) | VAF 275/464 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV101190126; called by muse, mutect2, varscan2
- ITPR3 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200526442, COSV65406184; called by muse, mutect2, varscan2
- ITPRID2 | c.2207G>T p.R736M | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100238646, COSV57477246; called by muse, mutect2, varscan2
- IZUMO1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55805965, COSV99711057; called by muse, mutect2
- IZUMO1 | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201149176, COSV99711058; called by muse, mutect2
- JAK1 | c.55A>G p.M19V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as COSV100692259; called by muse, mutect2, varscan2
- JAK3 | c.47G>C p.C16S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.15); catalogued as COSV101512999, COSV71686104; called by muse, mutect2
- JHY | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99913632; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2852C>T p.A951V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs144774902; called by muse, mutect2, varscan2
- JPH4 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as COSV100436984; called by muse, mutect2, varscan2
- KBTBD3 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231894324, COSV101595718; called by muse, mutect2, varscan2
- KCNB1 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.186); catalogued as COSV100870480, COSV100870571, COSV65568130; called by muse, mutect2, varscan2
- KCNB1 | c.2119G>T p.G707* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100870572; called by muse, mutect2, varscan2
- KCNB2 | c.2218A>T p.T740S | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.053); catalogued as COSV101578952; called by muse, mutect2, varscan2
- KCNC2 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | catalogued as COSV100129638; called by muse, mutect2, varscan2
- KCNH2 | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100060841; called by muse, mutect2, varscan2
- KCNH2 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100059187, COSV51136478; called by muse, mutect2, varscan2
- KCNH7 | c.2608G>C p.A870P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100149425, COSV59790871; called by muse, mutect2, varscan2
- KCNK10 | c.1077C>A p.S359R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069111, COSV56641030; called by muse, mutect2, varscan2
- KCNK9 | c.1034G>T p.S345I | Missense Mutation (SNP) | VAF 96/164 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV100271564; called by muse, mutect2, varscan2
- KCNN1 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55837046, COSV99716278; called by mutect2, varscan2
- KCNN3 | c.1120G>C p.A374P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55220412, COSV99679076; called by muse, mutect2, varscan2
- KCTD19 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV100431161; called by muse, mutect2, varscan2
- KCTD3 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV99379657; called by muse, mutect2, varscan2
- KDM4C | c.2858A>G p.Y953C | Missense Mutation (SNP) | VAF 90/132 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367739028; called by muse, mutect2, varscan2
- KDM5C | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100855494, COSV62890775; called by muse, mutect2, varscan2
- KDR | c.3967G>T p.E1323* | Nonsense Mutation (SNP) | VAF 89/240 reads (37%) | catalogued as COSV55768499, COSV99818463; called by muse, mutect2, varscan2
- KHDC1 | c.291G>A p.M97I (on ENST00000370384 / NM_001251874.2; = p.M24I on NM_030568.5) | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100001866, COSV100001948; called by muse, mutect2, varscan2
- KIAA1549L | c.2291C>A p.P764H (on ENST00000321505; = p.P1061H on NM_012194.3) | Missense Mutation (SNP) | VAF 94/199 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99684241; called by muse, mutect2, varscan2
- KIF19 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100739158; called by muse, mutect2
- KIF1A | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240924, COSV100242098; called by muse, mutect2, varscan2
- KIF1A | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242099, COSV57493914; called by muse, mutect2, varscan2
- KIF21A | c.1768G>T p.G590C (on ENST00000361418 / NM_001378440.1; = p.G577C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as COSV62779060; called by muse, mutect2, varscan2
- KIF21B | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100145012, COSV59766799; called by muse, mutect2, varscan2
- KIF5A | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs199608047, COSV54052333; called by muse, mutect2, varscan2
- KIF5C | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV101469557; called by muse, mutect2
- KIF6 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751660647, COSV99760301; called by muse, mutect2, varscan2
- KIF7 | c.3595C>T p.R1199C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as rs748917501, COSV51544256; called by muse, mutect2, varscan2
- KIFC1 | c.1828-1G>T p.X610_splice | Splice Site (SNP) | VAF 64/142 reads (45%) | catalogued as COSV100996109; called by muse, mutect2, varscan2
- KIR2DL3 | c.213C>G p.H71Q | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV99075380; called by muse, mutect2, varscan2
- KIR2DL4 | c.1045C>A p.Q349K (on ENST00000396284; = p.Q275K on NM_001080770.2) | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV100428852; called by muse, mutect2, varscan2
- KLF14 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100205969; called by muse, mutect2, varscan2
- KLHL17 | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as rs751897702, COSV100498062, COSV100498144; called by muse, mutect2, varscan2
- KLHL22 | c.1739A>T p.D580V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV99839427; called by muse, mutect2, varscan2
- KLHL26 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.071); catalogued as rs755391505, COSV99963341; called by muse, mutect2, varscan2
- KLHL38 | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100384546; called by muse, mutect2, varscan2
- KLHL4 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.082); catalogued as rs1410956050, COSV100910099; called by muse, mutect2, varscan2
- KLHL4 | c.1691G>C p.G564A | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.434); catalogued as COSV100909485, COSV100910100; called by muse, mutect2, varscan2
- KLK5 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as rs1568529383, COSV100307173; called by muse, mutect2, varscan2
- KMT2A | c.2534C>T p.T845I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV100629651; called by muse, mutect2, varscan2
- KMT2A | c.5414G>T p.W1805L | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV63285620, COSV99074522; called by muse, mutect2, varscan2
- KRT25 | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 121/246 reads (49%) | catalogued as rs753281477, COSV100380032; called by muse, mutect2, varscan2
- KRT35 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1471881867, COSV99877891; called by muse, mutect2
- KRTAP10-4 | c.798C>A p.C266* | Nonsense Mutation (SNP) | VAF 52/216 reads (24%) | catalogued as rs1555923462, COSV100555158; called by muse, mutect2, varscan2
- KRTAP20-2 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 85/142 reads (60%) | PolyPhen benign (0.165); catalogued as rs760841338, COSV100424534; called by muse, mutect2, varscan2
- KRTAP6-1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 49/101 reads (49%) | PolyPhen probably damaging (0.999); catalogued as COSV58168225; called by muse, mutect2, varscan2
- L3MBTL1 | c.2014G>T p.E672* (on ENST00000418998 / NM_001377303.1; = p.E582* on NM_015478.7) | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100917045; called by muse, mutect2, varscan2
- LANCL2 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV99635068; called by muse, mutect2, varscan2
- LBP | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99461210; called by muse, mutect2, varscan2
- LCMT1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101111768; called by muse, mutect2, varscan2
- LCP1 | c.685T>C p.W229R | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550039; called by muse, mutect2
- LDB1 | c.196C>T p.Q66* (on ENST00000425280 / NM_001321612.2; = p.Q30* on NM_003893.5) | Nonsense Mutation (SNP) | VAF 52/108 reads (48%) | catalogued as COSV100756453; called by muse, mutect2, varscan2
- LDLR | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52945880; called by muse, mutect2, varscan2
- LGI1 | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV101004472; called by muse, mutect2, varscan2
- LGR5 | c.2617A>T p.S873C | Missense Mutation (SNP) | VAF 138/241 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99878329; called by muse, mutect2, varscan2
- LHX1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs947853594; called by muse, mutect2
- LILRA6 | c.1143C>A p.F381L | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54445583, COSV99558021; called by muse, mutect2, varscan2
- LILRB1 | c.505C>G p.P169A (on ENST00000427581; = p.P133A on NM_006669.6) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100207722, COSV61121708; called by muse, varscan2
- LILRB3 | c.1143C>A p.F381L | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54445576; called by muse, mutect2
- LILRB5 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs749879962, COSV100300722; called by muse, mutect2, varscan2
- LIN7A | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV99692565; called by muse, mutect2, varscan2
- LINGO1 | c.1418G>T p.R473L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796486; called by muse, mutect2, varscan2
- LMX1A | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); catalogued as COSV99038768; called by muse, mutect2, varscan2
- LNPEP | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99183590; called by muse, mutect2, varscan2
- LPAR4 | c.842C>A p.T281N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.124); catalogued as COSV101425157; called by muse, mutect2, varscan2
- LPL | c.1140G>T p.L380= | Splice Region (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100255758; called by muse, mutect2, varscan2
- LRIT2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467063051, COSV100259312; called by muse, mutect2, varscan2
- LRP2 | c.3251G>T p.W1084L | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99789876; called by muse, mutect2, varscan2
- LRP4 | c.3074G>A p.G1025E | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.196); catalogued as COSV66138279; called by muse, mutect2, varscan2
- LRRC14B | c.1165C>G p.R389G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs770626524, COSV99723126; called by mutect2, varscan2
- LRRC18 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99630457; called by muse, mutect2, varscan2
- LRRC30 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.829); catalogued as COSV101274446; called by muse, mutect2, varscan2
- LRRC37A3 | c.425G>T p.R142M | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100141425; called by muse, mutect2, varscan2
- LRRC4C | c.1277G>T p.C426F | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99539357; called by muse, mutect2, varscan2
- LRRC7 | c.665C>G p.A222G (on ENST00000651989 / NM_001370785.2; = p.A189G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs755151095, COSV50543518, COSV99229145; called by muse, mutect2, varscan2
- LRRC7 | c.1441A>T p.S481C (on ENST00000651989 / NM_001370785.2; = p.S448C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229146; called by muse, mutect2, varscan2
- LRRCC1 | c.1181T>C p.L394S | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1217560570, COSV100835572; called by muse, mutect2
- LRRK1 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV52605887, COSV52621200; called by muse, mutect2, varscan2
- LRRTM3 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100791878; called by muse, mutect2, varscan2
- LRRTM3 | c.1217C>A p.P406Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV100791879; called by muse, mutect2, varscan2
- LSM7 | c.103G>T p.G35* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99395968; called by muse, mutect2
- LSM7 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99395972; called by muse, mutect2
- LUZP2 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100421048; called by muse, mutect2, varscan2
- LVRN | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV100773628; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV101012228, COSV65443270; called by muse, mutect2, varscan2
- LY75 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716892; called by muse, mutect2, varscan2
- MACF1 | c.19231C>T p.Q6411* (on ENST00000372915; = p.Q4456* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99246319; called by muse, mutect2, varscan2
- MAEL | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100901951; called by muse, mutect2, varscan2
- MAF | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391960; called by muse, mutect2, varscan2
- MAGEA10 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 127/196 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751437238, COSV54884775; called by muse, mutect2, varscan2
- MAGED2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99514721; called by muse, mutect2, varscan2
- MAGI2 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 88/301 reads (29%) | catalogued as COSV100836122; called by muse, mutect2, varscan2
- MAML2 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101594181, COSV73264815; called by muse, mutect2, varscan2
- MAN2A2 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as rs1185086709, COSV64637396; called by muse, mutect2, varscan2
- MAN2B2 | c.321T>A p.F107L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV99577935; called by muse, mutect2, varscan2
- MAP10 | c.1531C>A p.P511T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as COSV101406434, COSV101406542; called by muse, mutect2, varscan2
- MAP10 | c.2858A>T p.Q953L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs754465746, COSV101406543, COSV69363640; called by muse, mutect2, varscan2
- MAP2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV52280023; called by muse, mutect2, varscan2
- MAP2 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV99561426; called by muse, mutect2, varscan2
- MAP2K6 | c.881+1G>A p.X294_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100765125; called by muse, mutect2
- MAP4K2 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99581552; called by muse, mutect2, varscan2
- MAP4K3 | c.2115G>T p.M705I | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV99810967; called by muse, mutect2, varscan2
- MAU2 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99449067; called by muse, mutect2, varscan2
- MBD5 | c.3445A>T p.M1149L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV101289985, COSV101290239; called by muse, mutect2, varscan2
- MCM5 | c.1450G>T p.V484F | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775755762, COSV99331914; called by muse, mutect2, varscan2
- MDM4 | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100914490; called by muse, mutect2, varscan2
- MED12L | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs757116515, COSV99854351; called by muse, mutect2, varscan2
- MEP1A | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100043033; called by muse, mutect2, varscan2
- MEPE | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV63074140; called by muse, mutect2, varscan2
- METTL2B | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376529256, COSV99299958; called by muse, mutect2, varscan2
- MEX3B | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100314187; called by muse, mutect2, varscan2
- MFSD1 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV99964039; called by muse, mutect2, varscan2
- MGMT | c.436C>T p.Q146* (on ENST00000306010; = p.Q115* on NM_002412.5) | Nonsense Mutation (SNP) | VAF 63/126 reads (50%) | catalogued as rs763354641, COSV100023350, COSV100023975; called by muse, mutect2, varscan2
- MKRN3 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs146391768; called by muse, mutect2, varscan2
- MLIP | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99230274; called by muse, mutect2, varscan2
- MLX | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99519055; called by muse, mutect2, varscan2
- MLXIPL | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs369598943, COSV57667971; called by muse, mutect2
- MME | c.456A>T p.R152S | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100852503; called by muse, varscan2
- MME | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852504; called by muse, mutect2, varscan2
- MME | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100852505; called by muse, mutect2, varscan2
- MMP16 | c.1719G>T p.L573F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99689952; called by muse, mutect2, varscan2
- MMP8 | c.1305T>A p.H435Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV52632549; called by muse, mutect2, varscan2
- MMP8 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425249331, COSV52631657, COSV52632536; called by muse, mutect2, varscan2
- MMRN1 | c.3302T>A p.V1101E | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99307649; called by muse, mutect2, varscan2
- MOGAT3 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1265624153, COSV56176013, COSV99777288; called by muse, mutect2, varscan2
- MORC1 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99227475; called by muse, mutect2
- MPDZ | c.5481C>A p.S1827R (on ENST00000319217 / NM_001330637.2; = p.S1798R on NM_003829.5) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100057357; called by muse, mutect2, varscan2
- MPDZ | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100064246; called by muse, mutect2, varscan2
- MRGPRX3 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV101283577; called by muse, mutect2, varscan2
- MRPL49 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99589249; called by muse, mutect2, varscan2
- MRPS27 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV54650192; called by muse, mutect2, varscan2
- MRTFB | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100371732; called by muse, mutect2, varscan2
- MSC | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs768188608, COSV100335861; called by muse, mutect2, varscan2
- MSH4 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV54195759; called by muse, mutect2, varscan2
- MTNR1B | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 96/287 reads (33%) | catalogued as COSV99925288; called by muse, mutect2, varscan2
- MTOR | c.6886G>T p.G2296W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816595; called by muse, mutect2, varscan2
- MTRES1 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs1344356870, COSV100261221; called by muse, mutect2, varscan2
- MTRR | c.1502A>G p.E501G (on ENST00000264668; = p.E474G on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99242004; called by muse, mutect2, varscan2
- MUC16 | c.38601G>T p.Q12867H | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV101201140; called by muse, mutect2, varscan2
- MUC16 | c.30011C>A p.P10004H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV101201143; called by muse, mutect2, varscan2
- MUC16 | c.28333C>T p.P9445S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.637); catalogued as rs950238989, COSV101199572, COSV67481080; called by muse, mutect2, varscan2
- MUC16 | c.10438G>A p.G3480R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.216); catalogued as COSV101201144; called by muse, mutect2
- MUC16 | c.10071C>A p.D3357E | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.246); catalogued as COSV101201145; called by muse, mutect2, varscan2
- MUC16 | c.5477A>T p.E1826V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV101201146; called by muse, mutect2, varscan2
- MUC16 | c.4472C>A p.P1491H | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101201148, COSV67492776; called by muse, mutect2, varscan2
- MUC17 | c.13429C>A p.P4477T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.292); catalogued as COSV100074747; called by muse, mutect2, varscan2
- MUC17 | c.13430C>A p.P4477H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV100074748; called by muse, mutect2, varscan2
- MUC4 | c.2762C>G p.T921S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.301); catalogued as rs746810993, COSV62213390; called by muse, mutect2, varscan2
- MXRA5 | c.6869A>G p.Q2290R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99478793; called by muse, mutect2, varscan2
- MXRA5 | c.6868C>A p.Q2290K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV99478795; called by muse, mutect2, varscan2
- MXRA5 | c.1675G>C p.V559L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99478798; called by muse, mutect2, varscan2
- MYCBP2 | c.9243G>T p.K3081N (on ENST00000357337; = p.K3119N on NM_015057.5) | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV100631492; called by muse, mutect2, varscan2
- MYCBP2 | c.6317G>A p.G2106E (on ENST00000357337; = p.G2144E on NM_015057.5) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62010706; called by muse, mutect2, varscan2
- MYH1 | c.3808C>T p.Q1270* | Nonsense Mutation (SNP) | VAF 23/132 reads (17%) | catalogued as COSV99876678; called by muse, mutect2, varscan2
- MYH11 | c.3274C>A p.L1092M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV100260010; called by muse, mutect2, varscan2
- MYH2 | c.4372-1G>T p.X1458_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99820773; called by muse, mutect2, varscan2
- MYH8 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 120/239 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV101238649; called by muse, mutect2, varscan2
- MYO18B | c.3952G>T p.V1318F | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124863; called by muse, mutect2, varscan2
- MYO3B | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100511453; called by muse, mutect2, varscan2
- MYO7A | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs376701580, COSV101289247; called by muse, mutect2, varscan2
- MYRF | c.1722C>A p.H574Q (on ENST00000278836 / NM_001127392.3; = p.H565Q on NM_013279.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs1263104387, COSV99607748; called by muse, mutect2, varscan2
- NAALAD2 | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100428722; called by muse, mutect2, varscan2
- NAB1 | c.974A>G p.D325G | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.516); catalogued as COSV100493136; called by muse, mutect2, varscan2
- NAE1 | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV99322997, COSV99323198; called by muse, mutect2, varscan2
- NAPB | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV100794105; called by muse, varscan2
- NAV3 | c.1192del p.R398Afs*33 | Frame Shift Del (DEL) | VAF 76/165 reads (46%) | catalogued as COSV57077197; called by mutect2, pindel, varscan2
- NAV3 | c.4498A>C p.N1500H | Missense Mutation (SNP) | VAF 99/147 reads (67%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.705); catalogued as COSV99894539; called by muse, mutect2, varscan2
- NBAS | c.2005G>C p.V669L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs142006451; called by muse, mutect2, varscan2
- NBAS | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104386095, COSV99871290; called by muse, mutect2, varscan2
- NCAM1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100378385; called by muse, mutect2, varscan2
- NCAM1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV100378387; called by muse, mutect2, varscan2
- NCAM1 | c.1114C>A p.R372S (on ENST00000316851 / NM_181351.5; = p.R362S on NM_000615.7) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1555117239, COSV100378388; called by muse, mutect2, varscan2
- NCKAP5 | c.2584G>C p.D862H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100493936; called by muse, mutect2, varscan2
- NCKAP5 | c.2332C>A p.H778N | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV100493937; called by muse, mutect2, varscan2
- NCKAP5L | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100259126; called by muse, mutect2, varscan2
- NDST2 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV55213930; called by muse, mutect2, varscan2
- NEB | c.9353C>T p.T3118M | Missense Mutation (SNP) | VAF 71/357 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs745706462, COSV99426840; called by muse, mutect2, varscan2
- NEBL | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as COSV101009315; called by muse, mutect2, varscan2
- NELL1 | c.1417T>A p.S473T | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV100124125; called by muse, mutect2, varscan2
- NETO2 | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV100292574; called by muse, mutect2, varscan2
- NEU2 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99290707; called by muse, mutect2, varscan2
- NEUROG3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917838, CM066146, COSV54343640; called by muse, mutect2, varscan2
- NF1 | c.2515A>T p.N839Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100648036, COSV62203277; called by muse, mutect2, varscan2
- NID1 | c.2546G>T p.C849F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99936999, COSV99938156; called by muse, mutect2, varscan2
- NID2 | c.2540C>A p.P847Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as COSV53504428; called by muse, mutect2, varscan2
- NINL | c.3453G>T p.Q1151H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99626025; called by muse, mutect2, varscan2
- NISCH | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1344315704, COSV100617631; called by muse, mutect2, varscan2
- NKAIN2 | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 46/101 reads (46%) | catalogued as COSV100863841; called by muse, mutect2, varscan2
- NLGN1 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 88/295 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV64324732; called by muse, mutect2, varscan2
- NLGN2 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV100192890; called by muse, mutect2, varscan2
- NLRP10 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100149917, COSV60779732; called by muse, mutect2, varscan2
- NMS | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100966643, COSV65259288; called by muse, mutect2, varscan2
- NMU | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.421); catalogued as rs1365299059, COSV51701304, COSV99946806; called by muse, mutect2, varscan2
- NMUR2 | c.614C>A p.T205K | Missense Mutation (SNP) | VAF 138/240 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV54917555, COSV99677224; called by muse, mutect2, varscan2
- NOTCH3 | c.1491G>C p.S497= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99658559; called by muse, mutect2, varscan2
- NOTCH4 | c.2921C>A p.S974Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100900939; called by muse, mutect2, varscan2
- NOTCH4 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1382478531, COSV100900497; called by muse, mutect2, varscan2
- NOX4 | c.776C>A p.A259E | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99630603, COSV99631624; called by muse, mutect2, varscan2
- NOXO1 | c.837C>A p.Y279* (on ENST00000397280 / NM_172168.3; = p.Y273* on NM_144603.4) | Nonsense Mutation (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99937093; called by muse, mutect2, varscan2
- NPAP1 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as COSV100275992; called by muse, mutect2, varscan2
- NPAP1 | c.1293C>A p.D431E | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV100275996, COSV61506819; called by muse, mutect2, varscan2
- NPAS4 | c.2206C>A p.P736T | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV100215198; called by muse, mutect2, varscan2
- NPC1 | c.3592-1G>A p.X1198_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99340373; called by muse, mutect2, varscan2
- NPC1L1 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV99213342; called by muse, mutect2, varscan2
- NPIPB15 | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV101466035; called by muse, mutect2, varscan2
- NPR1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100902066; called by muse, mutect2, varscan2
- NPR2 | c.1058A>C p.Q353P | Missense Mutation (SNP) | VAF 147/235 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.359); catalogued as COSV100709674; called by muse, mutect2, varscan2
- NPY | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99636005; called by muse, mutect2
- NPY | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99636009; called by muse, mutect2, varscan2
- NRCAM | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100695309, COSV61032682; called by muse, mutect2, varscan2
- NRXN2 | c.3477C>A p.S1159R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV99635451; called by muse, mutect2, varscan2
- NSD1 | c.3542A>T p.E1181V | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV100729731; called by muse, mutect2, varscan2
- NSD3 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100388868; called by muse, mutect2, varscan2
- NTMT1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs769308190, COSV99475830; called by muse, mutect2, varscan2
- NTSR1 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs746002141, COSV100980701; called by muse, mutect2, varscan2
- NUAK1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 74/97 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54602125; called by muse, mutect2, varscan2
- NUAK2 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765807541, COSV100904137; called by muse, mutect2, varscan2
- NUMB | c.1357G>T p.A453S (on ENST00000355058; = p.A442S on NM_003744.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV99390290; called by muse, mutect2, varscan2
- NUP133 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99773351; called by muse, mutect2, varscan2
- NUP133 | c.1891G>A p.G631R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99773354, COSV99773554; called by muse, mutect2, varscan2
- NUP93 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs747730206; called by muse, mutect2
- NXPE4 | c.1218G>T p.M406I (on ENST00000375478 / NM_001077639.2; = p.M122I on NM_017678.3) | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100970540; called by muse, mutect2, varscan2
- NYNRIN | c.3977G>T p.G1326V | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101230672; called by muse, mutect2, varscan2
- OAS3 | c.3133A>T p.T1045S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99966514; called by muse, mutect2, varscan2
- OBSCN | c.8014G>T p.D2672Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV52745892, COSV99483103; called by muse, mutect2, varscan2
- OBSCN | c.10073G>T p.R3358M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV99483109; called by muse, mutect2, varscan2
- OBSCN | c.22291G>A p.G7431S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100805209; called by muse, mutect2, varscan2
- OGDH | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.513); catalogued as COSV99759494; called by muse, mutect2, varscan2
- OLFM3 | c.1076T>C p.V359A (on ENST00000338858 / NM_001288821.1; = p.V339A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100129960; called by muse, mutect2, varscan2
- OPCML | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.249); catalogued as COSV100098884, COSV59417502, COSV59451112; called by muse, varscan2
- OPN4 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.208); catalogued as COSV99618746; called by muse, mutect2, varscan2
- OR10AG1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV100400175, COSV56631311; called by muse, mutect2, varscan2
- OR10G7 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100389993; called by muse, mutect2
- OR14C36 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV100507623; called by muse, mutect2, varscan2
- OR14I1 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100700533; called by muse, varscan2
- OR1A2 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101126382, COSV67936242; called by muse, mutect2, varscan2
- OR1C1 | c.922T>G p.C308G | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101376269; called by muse, mutect2, varscan2
- OR1G1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100187589; called by muse, mutect2, varscan2
- OR2A5 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101278828; called by muse, mutect2, varscan2
- OR2AG1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs368714829, COSV100264952; called by muse, mutect2, varscan2
- OR2B11 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV100276523; called by muse, mutect2, varscan2
- OR2D3 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100505126; called by muse, mutect2, varscan2
- OR2F2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778803079, COSV101283845; called by muse, mutect2, varscan2
- OR2M2 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100677299; called by muse, varscan2
- OR2M2 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100677187, COSV100677301; called by muse, varscan2
- OR2M2 | c.607T>C p.C203R | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100677303; called by muse, varscan2
- OR2T11 | c.566C>G p.T189R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100424929, COSV58186330; called by muse, mutect2, varscan2
- OR2T4 | c.286A>T p.S96C | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100822582; called by muse, mutect2, varscan2
- OR3A1 | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100041812; called by muse, mutect2, varscan2
- OR4B1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs149306992; called by muse, mutect2, varscan2
- OR4C3 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs756896514, COSV100168213, COSV60586906; called by muse, mutect2, varscan2
- OR4D10 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101597023, COSV101597025; called by muse, mutect2, varscan2
954 further variants in this file (537 protein-altering or splice-affecting, 363 silent, 54 other) are not listed here.
